National Lung Screening Trial (NLST) participant 123488 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 59 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 41): Negative screen, no significant abnormalities. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 160 mA, 40 effective mAs, display field of view 36 cm, reconstruction filter Siemens B50F.
- T1 (day 400): Negative screen, no significant abnormalities. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 90 mA, 30 effective mAs, display field of view 34 cm, reconstruction filter Siemens B50F.
- T2 (day 717): Negative screen, no significant abnormalities. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 120 mA, 30 effective mAs, display field of view 37 cm, reconstruction filter Siemens B50F.

No rows exist for this participant in the CT abnormalities table.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,214.
